Somatic mutation profile of tumor specimen TCGA-AP-A1DR-01A (aliquot TCGA-AP-A1DR-01A-11D-A135-09) from TCGA case TCGA-AP-A1DR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G2; Age at diagnosis: 60.0 years (21,904 days).
Specimen TCGA-AP-A1DR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de4433cd-2d34-455c-85b5-9afbfd981611.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A1DR-10A (Blood Derived Normal), aliquot TCGA-AP-A1DR-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/583bc6e1-241d-4770-826a-569ce56d53fd

The open-access MAF lists 867 somatic variants for this specimen: 666 protein-altering or splice-affecting, 171 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 407, Silent 171, Frame Shift Del 170, Frame Shift Ins 36, Nonsense Mutation 26, Splice Site 15, Intron 15, RNA 8, Splice Region 6, 3'Flank 4, In Frame Del 4, Translation Start Site 2.

Variants (750 of 867; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B1 | c.614dup p.N205Kfs*2 | Frame Shift Ins (INS) | VAF 16/50 reads (32%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- EFEMP2 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs397514683, CM127922, COSV57260968; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- KCNQ1 | c.1265del p.K422Sfs*10 | Frame Shift Del (DEL) | VAF 47/126 reads (37%) | catalogued as rs397508083; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KMT2A | c.2318del p.P773Rfs*8 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- LDLR | c.2270del p.P757Lfs*8 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs1131692223, COSV52943181; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 36/74 reads (49%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- PALB2 | c.839del p.N280Tfs*8 | Frame Shift Del (DEL) | VAF 7/70 reads (10%) | catalogued as rs1555461597; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3R1 | c.1699A>G p.K567E (on ENST00000521381 / NM_181523.3; = p.K297E on NM_181504.4) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV57123609; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 58/90 reads (64%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCB5 | c.2284G>A p.E762K (on ENST00000404938 / NM_001163941.2; = p.E317K on NM_178559.6) | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs866674219, COSV99329255; called by muse, varscan2
- ABCB8 | c.1757G>A p.R586Q (on ENST00000297504 / NM_001282291.2; = p.R569Q on NM_007188.5) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.148); catalogued as rs374442680; called by muse, varscan2
- ABCC6 | c.3847C>T p.Q1283* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99229577; called by muse, mutect2, varscan2
- ABCG8 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775468682, COSV55396213; called by muse, mutect2, varscan2
- ABHD1 | c.207T>A p.C69* | Nonsense Mutation (SNP) | VAF 28/145 reads (19%) | catalogued as COSV99574807; called by muse, mutect2, varscan2
- AC127029.3 | c.304C>A p.L102M | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV100033355; called by muse, mutect2, varscan2
- ACSL6 | c.1060G>T p.D354Y (on ENST00000379240; = p.D379Y on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99734590; called by muse, mutect2, varscan2
- ACSM5 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs566907774, COSV59369559; called by muse, mutect2, varscan2
- ACSM5 | c.1654A>G p.K552E | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100089505; called by muse, varscan2
- ACSS3 | c.780+2T>C p.X260_splice | Splice Site (SNP) | VAF 20/34 reads (59%) | catalogued as rs756902874, COSV54088434; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 25/100 reads (25%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM30 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs761413158, COSV101023973; called by muse, varscan2
- ADAMTSL1 | c.5137C>T p.R1713W | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs754877575, COSV101000908; called by muse, mutect2, varscan2
- ADCY4 | c.819C>T p.S273= | Splice Region (SNP) | VAF 43/87 reads (49%) | catalogued as rs376471269; called by muse, mutect2, varscan2
- ADCY6 | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs781510708, COSV100326887; called by muse, varscan2
- ADGRF5 | c.3148C>T p.R1050C | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51932322; called by muse, mutect2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | catalogued as rs761350619; called by mutect2, varscan2
- ALG13 | c.714G>T p.K238N | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99322978; called by muse, mutect2, varscan2
- ALPK2 | c.47C>A p.S16Y | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100864782, COSV64491562; called by muse, mutect2
- ANAPC11 | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100326037, COSV58711530; called by muse, mutect2, varscan2
- ANAPC5 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99946469; called by muse, mutect2, varscan2
- ANKRD11 | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs776780527, COSV56376470; called by muse, mutect2, varscan2
- ANKRD12 | c.5371C>T p.R1791C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1324628142, COSV100042045; called by muse, mutect2, varscan2
- ANKRD2 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as rs755630370, COSV100081053; called by muse, mutect2, varscan2
- ANKS1A | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.475); catalogued as rs747927538, COSV100832808; called by muse, mutect2, varscan2
- ANO2 | c.1957G>A p.V653I (on ENST00000356134 / NM_001278597.3; = p.V657I on NM_001278596.3) | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as rs755546576, COSV100501659; called by muse, mutect2, varscan2
- ANPEP | c.2752-1G>A p.X918_splice | Splice Site (SNP) | VAF 17/56 reads (30%) | catalogued as rs1375302022, COSV100262752, COSV100263485; called by muse, mutect2, varscan2
- APC | c.6579del p.V2194Ffs*5 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as rs775076289; called by mutect2, pindel, varscan2
- APMAP | c.945del p.Y316Tfs*29 | Frame Shift Del (DEL) | VAF 19/47 reads (40%) | catalogued as rs777444320; called by mutect2, varscan2
- APOBEC3F | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100415262; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 68/162 reads (42%) | catalogued as rs749401724; called by mutect2, varscan2
- ARAP3 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1400805449, COSV99500246; called by muse, mutect2, varscan2
- ARHGAP44 | c.2288G>A p.G763D | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.898); catalogued as rs868357275, COSV99311470; called by muse, mutect2
- ARID1A | c.4336C>T p.R1446* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV61370903, COSV61383151; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 95/134 reads (71%) | catalogued as rs761154268; called by mutect2, varscan2
- ASIC4 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100761920; called by muse, mutect2
- ASTN2 | c.3671C>T p.T1224I (on ENST00000313400 / NM_001365069.1; = p.T1173I on NM_014010.5) | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1213280142, COSV99941651; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52354921; called by muse, mutect2, varscan2
- ATP7A | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.375); catalogued as COSV100431651; called by muse, mutect2, varscan2
- ATXN2L | c.1907C>T p.P636L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs564157371, COSV100295126, COSV57369242; called by muse, varscan2
- AXL | c.637del p.V213Sfs*37 | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | catalogued as COSV56565516; called by mutect2, varscan2
- BHMT | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99165517; called by muse, mutect2, varscan2
- BHMT | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs201307547, COSV57153740; called by muse, mutect2, varscan2
- BPIFB4 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100971657; called by muse, mutect2, varscan2
- BTBD2 | c.1316G>A p.G439D | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.845); catalogued as COSV99724958; called by muse, mutect2, varscan2
- BTN2A1 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV100438775; called by muse, mutect2, varscan2
- BUD13 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99496734; called by muse, mutect2, varscan2
- C1QTNF4 | c.866A>T p.H289L | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.912); catalogued as COSV100209394; called by muse, mutect2, varscan2
- C1orf216 | c.656G>T p.R219M | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV52054334, COSV99231479; called by muse, mutect2, varscan2
- C1orf87 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV100967246; called by muse, mutect2, varscan2
- C2orf73 | c.179G>C p.R60T | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100471498; called by muse, mutect2, varscan2
- C3orf22 | c.87C>T p.Y29= | Splice Region (SNP) | VAF 31/73 reads (42%) | catalogued as COSV100559554; called by muse, mutect2, varscan2
- C3orf38 | c.443G>T p.W148L | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100007487; called by muse, mutect2, varscan2
- C4orf17 | c.253del p.S85Pfs*10 | Frame Shift Del (DEL) | VAF 37/115 reads (32%) | catalogued as rs201447915; called by mutect2, pindel, varscan2
- C5orf22 | c.772del p.S258Qfs*31 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs751259551; called by mutect2, varscan2
- C9orf152 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 21/40 reads (53%) | catalogued as COSV101272402; called by muse, mutect2, varscan2
- CACNA1E | c.3458G>A p.R1153H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs747254914, COSV100702594; called by muse, mutect2, varscan2
- CACNA1E | c.5083G>A p.G1695S | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1160971846, COSV62381053; called by muse, mutect2, varscan2
- CALR3 | c.1120T>C p.Y374H | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV99522330; called by muse, mutect2, varscan2
- CAMSAP3 | c.1006del p.R336Gfs*42 | Frame Shift Del (DEL) | VAF 22/44 reads (50%) | catalogued as rs754747174; called by mutect2, varscan2
- CANT1 | c.392del p.K131Rfs*4 | Frame Shift Del (DEL) | VAF 13/88 reads (15%) | catalogued as COSV56605000; called by mutect2, pindel, varscan2
- CAPN6 | c.1399T>C p.Y467H | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100137056; called by muse, mutect2, varscan2
- CARD16 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 88/206 reads (43%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.781); catalogued as rs577987861, COSV100995118; called by muse, mutect2, varscan2
- CASS4 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.391); catalogued as rs775410880, COSV100824972, COSV64386145; called by muse, mutect2, varscan2
- CATSPERE | c.1706A>G p.H569R | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100835368; called by muse, mutect2, varscan2
- CBLL1 | c.1163dup p.G389Wfs*37 | Frame Shift Ins (INS) | VAF 20/91 reads (22%) | catalogued as rs1405669921; called by mutect2, pindel, varscan2
- CC2D2A | c.1730C>T p.S577L | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs543650388, COSV67502578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 73/198 reads (37%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 39/118 reads (33%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC57 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs757942091, COSV100492600; called by muse, varscan2
- CCNA1 | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 28/89 reads (31%) | catalogued as rs373856311; called by muse, mutect2, varscan2
- CD93 | c.943dup p.A315Gfs*34 | Frame Shift Ins (INS) | VAF 39/109 reads (36%) | catalogued as rs747115137; called by mutect2, varscan2
- CDC123 | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99827202; called by muse, mutect2, varscan2
- CDH10 | c.2187del p.Y730Tfs*19 | Frame Shift Del (DEL) | VAF 37/114 reads (32%) | catalogued as rs1273877423; called by mutect2, pindel, varscan2
- CDHR1 | c.2203C>T p.P735S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100259353; called by muse, mutect2, varscan2
- CDK5RAP1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100212277; called by muse, mutect2, varscan2
- CDKL3 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs535495505, COSV54743341; called by muse, mutect2, varscan2
- CEP152 | c.3059T>C p.L1020P | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100359135; called by muse, mutect2, varscan2
- CEP290 | c.7153del p.I2385* | Frame Shift Del (DEL) | VAF 28/74 reads (38%) | catalogued as rs781310385; called by mutect2, pindel, varscan2
- CFAP91 | c.1583C>T p.T528I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.816); catalogued as rs1457747275, COSV56342631; called by muse, mutect2, varscan2
- CGB8 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 74/261 reads (28%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs1389582639, COSV100032126, COSV56822684; called by muse, mutect2, varscan2
- CGNL1 | c.2420C>T p.A807V | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.079); catalogued as rs780359042, COSV55564717; called by muse, mutect2, varscan2
- CHD3 | c.4142G>A p.R1381H | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1165994865, COSV100391656; called by muse, mutect2, varscan2
- CIZ1 | c.1835T>C p.M612T | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99477120; called by muse, mutect2, varscan2
- CLDN10 | c.37G>C p.V13L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100176266; called by muse, mutect2, varscan2
- CLDN8 | c.622del p.S208Vfs*33 | Frame Shift Del (DEL) | VAF 41/136 reads (30%) | catalogued as rs769497921, COSV54527445; called by mutect2, pindel, varscan2
- CLIC1 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1366392033, COSV101007556; called by muse, mutect2, varscan2
- CNTN5 | c.472A>G p.I158V | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.991); catalogued as rs770916776, COSV99681068; called by muse, mutect2, varscan2
- COG4 | c.2146A>G p.I716V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs886052257, COSV99851249; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs761770226, COSV65666859; called by muse, mutect2, varscan2
- COL5A1 | c.2087C>A p.P696H | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100880561; called by muse, mutect2, varscan2
- COL5A1 | c.2730del p.Q911Sfs*163 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as COSV65676186; called by mutect2, pindel, varscan2
- COL5A1 | c.4050dup p.G1351Rfs*14 | Frame Shift Ins (INS) | VAF 34/84 reads (40%) | catalogued as rs758337699; called by mutect2, varscan2
- COL5A2 | c.1105-1G>T p.X369_splice | Splice Site (SNP) | VAF 32/74 reads (43%) | catalogued as COSV100880775, COSV66407646; called by muse, mutect2, varscan2
- COL5A3 | c.2999del p.P1000Qfs*144 | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | catalogued as rs760926657; called by mutect2, pindel, varscan2
- COLEC12 | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101232162; called by muse, mutect2, varscan2
- COLGALT1 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV53111389; called by muse, mutect2
- COP1 | c.1183T>C p.C395R | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.962); catalogued as COSV100443883; called by muse, varscan2
- CPLANE2 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767538456, COSV100983286; called by muse, varscan2
- CRACD | c.3032G>A p.S1011N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as COSV99949975; called by muse, mutect2, varscan2
- CREBBP | c.4807G>A p.A1603T | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.241); catalogued as rs375557093, COSV52117791; called by muse, mutect2, varscan2
- CRISP1 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100237090, COSV59993662; called by muse, mutect2, varscan2
- CROT | c.102del p.K34Nfs*6 | Frame Shift Del (DEL) | VAF 30/68 reads (44%) | catalogued as rs756999481; called by mutect2, pindel, varscan2
- CRTC2 | c.159G>T p.Q53H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100135688; called by muse, mutect2, varscan2
- CSMD2 | c.4406A>C p.K1469T | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99594973; called by muse, mutect2, varscan2
- CSTA | c.125A>G p.Q42R | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs200946159, COSV52612346; called by muse, mutect2, varscan2
- CTNNBL1 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.308); catalogued as COSV100799832; called by muse, mutect2, varscan2
- CUL3 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.821); catalogued as COSV100024558, COSV52363756; called by muse, mutect2, varscan2
- CYFIP1 | c.3296G>A p.R1099Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.727); catalogued as rs1020500529, COSV100488763, COSV100488765; called by muse, mutect2
- CYP4F3 | c.527C>G p.A176G | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99658691; called by muse, mutect2, varscan2
- DCX | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as rs753011298, COSV57573868; called by muse, mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs772416332; called by mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 62/72 reads (86%) | catalogued as rs553532837; called by mutect2, varscan2
- DHH | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs199552954, COSV57202892; called by muse, mutect2, varscan2
- DHX34 | c.3158C>T p.T1053M | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs376039446; called by muse, varscan2
- DIAPH1 | c.2108del p.P703Hfs*65 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as rs771360300; called by mutect2, varscan2
- DLEC1 | c.3025G>A p.G1009R | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372104796; called by muse, mutect2, varscan2
- DLG1 | c.1760G>T p.R587I | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100015533, COSV58385977; called by muse, mutect2, varscan2
- DLGAP2 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.165); catalogued as rs759524900, COSV70104066; called by muse, mutect2, varscan2
- DLGAP4 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs149955874, COSV59420026; called by muse, varscan2
- DLL3 | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV99219491; called by muse, mutect2, varscan2
- DMTN | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99742175; called by muse, mutect2, varscan2
- DNAH1 | c.4207C>T p.R1403C | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as rs763267782, COSV101327005; called by muse, mutect2, varscan2
- DNAH3 | c.9170C>T p.A3057V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV99770450; called by muse, mutect2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 9/84 reads (11%) | catalogued as rs782552436; called by mutect2, pindel
- DSP | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs200476515, CM150653; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- DUSP8 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100524517; called by muse, mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 32/60 reads (53%) | catalogued as rs772082432; called by mutect2, varscan2
- EDEM3 | c.1974del p.F658Lfs*4 | Frame Shift Del (DEL) | VAF 29/82 reads (35%) | catalogued as rs1173052284; called by mutect2, pindel, varscan2
- EDIL3 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs757863733, COSV56879041; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs1284210456, COSV100668842; called by muse, mutect2
- EIF3K | c.175G>C p.A59P | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99943184; called by muse, mutect2, varscan2
- EIF5B | c.1497G>T p.E499D | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV56812662, COSV99178795; called by muse, mutect2, varscan2
- ELK1 | c.67A>G p.I23V | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as COSV99902346; called by muse, mutect2, varscan2
- ELOVL5 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100439920; called by muse, mutect2, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs770453803; called by mutect2, varscan2
- EP400 | c.5539C>T p.R1847C | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs554178502, COSV57770617; called by muse, mutect2, varscan2
- EPB42 | c.736C>T p.R246W (on ENST00000441366 / NM_001114134.2; = p.R276W on NM_000119.3) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs770888181, COSV100282138; called by muse, mutect2, varscan2
- EPHA5 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56630361; called by muse, mutect2, varscan2
- EPHB1 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67653779; called by muse, mutect2, varscan2
- EPHB6 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as rs1354122456, COSV101235997; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 25/96 reads (26%) | catalogued as rs775950025; called by mutect2, varscan2
- EXOC3 | c.1447C>A p.P483T | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.232); catalogued as COSV100155581; called by muse, varscan2
- EXOC3 | c.2114G>A p.R705H | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV100155582; called by muse, mutect2, varscan2
- FAHD2B | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 20/98 reads (20%) | catalogued as rs751966944; called by mutect2, pindel, varscan2
- FAM131A | c.768dup p.S257Qfs*60 (on ENST00000310585; = p.S288Qfs*60 on NM_144635.5) | Frame Shift Ins (INS) | VAF 43/124 reads (35%) | catalogued as rs1560244745; called by mutect2, pindel, varscan2
- FAM135B | c.4015G>T p.G1339W | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99423874; called by muse, mutect2, varscan2
- FAM166A | c.895G>A p.G299S | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs758392300, COSV100458180; called by muse, mutect2, varscan2
- FAM47A | c.631C>A p.L211I | Missense Mutation (SNP) | VAF 99/260 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.199); catalogued as COSV100650062, COSV60500224; called by muse, mutect2, varscan2
- FAM47C | c.1787del p.P596Rfs*229 | Frame Shift Del (DEL) | VAF 112/344 reads (33%) | catalogued as COSV63724780; called by mutect2, pindel, varscan2
- FANCD2 | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99812422; called by muse, mutect2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 22/44 reads (50%) | catalogued as rs746983128; called by mutect2, varscan2
- FAR1 | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100701656; called by muse, mutect2, varscan2
- FARP1 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV60335545; called by muse, mutect2, varscan2
- FASLG | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.716); catalogued as rs61761322, COSV60680147; called by muse, mutect2, varscan2
- FAT2 | c.10383dup p.Y3462Lfs*26 | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | catalogued as rs747011618; called by mutect2, varscan2
- FBN3 | c.2259del p.G754Afs*23 | Frame Shift Del (DEL) | VAF 26/63 reads (41%) | catalogued as COSV54456788; called by mutect2, pindel, varscan2
- FBXL13 | c.69C>T p.C23= | Splice Region (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100502087; called by muse, mutect2, varscan2
- FBXO21 | c.505dup p.I169Nfs*13 | Frame Shift Ins (INS) | VAF 28/72 reads (39%) | catalogued as rs34443379; called by mutect2, varscan2
- FBXO22 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV100380667; called by muse, mutect2, varscan2
- FBXO31 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1294566807, COSV61148183; called by muse, mutect2, varscan2
- FBXW5 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.113); catalogued as COSV99812677; called by muse, mutect2, varscan2
- FCGBP | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.281); catalogued as rs1305487051; called by muse, mutect2, varscan2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 18/96 reads (19%) | catalogued as rs1288807478; called by mutect2, pindel, varscan2
- FER | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 59/113 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs151332661, COSV55300024; called by muse, mutect2, varscan2
- FLNA | c.5174G>A p.R1725H (on ENST00000369850 / NM_001110556.2; = p.R1717H on NM_001456.3) | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV100774615; called by muse, mutect2, varscan2
- FNDC3B | c.1466C>T p.T489I | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV100394898; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 23/55 reads (42%) | catalogued as rs760347049; called by mutect2, pindel, varscan2
- FOXS1 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as rs769554578, COSV99640201; called by muse, mutect2, varscan2
- FREM1 | c.5239C>T p.Q1747* | Nonsense Mutation (SNP) | VAF 39/87 reads (45%) | catalogued as rs755815570, COSV101085421; called by muse, mutect2, varscan2
- FRMD7 | c.1951A>C p.S651R | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100049273; called by muse, mutect2, varscan2
- FRMD7 | c.1312del p.S438Qfs*6 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs1459947409; called by mutect2, pindel, varscan2
- FRY | c.1856G>T p.G619V | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV100969886; called by muse, mutect2, varscan2
- FYB1 | c.1663G>C p.A555P | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV100685249, COSV100686328; called by muse, mutect2, varscan2
- FZD5 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.091); catalogued as COSV99776509; called by muse, mutect2
- GAB1 | c.50dup p.E18Gfs*34 | Frame Shift Ins (INS) | VAF 32/76 reads (42%) | catalogued as rs755581817; called by mutect2, varscan2
- GAD2 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as rs754627728, COSV52150827, COSV52170231; called by muse, mutect2, varscan2
- GBE1 | c.2011del p.S671Lfs*36 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | catalogued as rs780374709; called by mutect2, pindel, varscan2
- GBP5 | c.731del p.K244Sfs*13 | Frame Shift Del (DEL) | VAF 45/99 reads (45%) | catalogued as rs34148688; called by mutect2, pindel, varscan2
- GDF7 | c.1126T>C p.Y376H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.893); catalogued as COSV55348213; called by muse, mutect2, varscan2
- GEMIN5 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99501806; called by muse, mutect2, varscan2
- GFRA1 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as rs191814086; called by muse, mutect2, varscan2
- GHITM | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100930137; called by muse, mutect2, varscan2
- GKN1 | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.902); catalogued as COSV65006492; called by muse, mutect2, varscan2
- GLDC | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.577); catalogued as COSV100394574, COSV58680253; called by muse, mutect2, varscan2
- GLUL | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.331); catalogued as COSV100092300; called by muse, mutect2, varscan2
- GOLGA2 | c.2929del p.Y977Tfs*9 | Frame Shift Del (DEL) | VAF 23/103 reads (22%) | catalogued as rs763679060; called by mutect2, varscan2
- GOLGA2 | c.2213A>G p.E738G | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100360311; called by muse, mutect2, varscan2
- GP6 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV59979172; called by muse, mutect2, varscan2
- GPAT3 | c.1277T>C p.M426T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV100023281; called by muse, mutect2, varscan2
- GPR89B | c.54dup p.G19Wfs*13 | Frame Shift Ins (INS) | VAF 49/120 reads (41%) | catalogued as rs1351486989; called by mutect2, pindel, varscan2
- GRHL1 | c.702G>A p.M234I | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.21); catalogued as COSV100258155; called by muse, mutect2, varscan2
- GRM4 | c.2517G>A p.M839I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.071); catalogued as COSV100946861; called by muse, mutect2, varscan2
- GRM6 | c.2525T>C p.V842A | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs972036274, COSV51435759; called by muse, mutect2, varscan2
- GSR | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as COSV99645832; called by muse, mutect2, varscan2
- GSR | c.332del p.K111Rfs*2 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as rs34855738; called by mutect2, pindel, varscan2
- GTF3C5 | c.734C>A p.P245H | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV100565557; called by muse, mutect2, varscan2
- HAO2 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs765518257, COSV58040369; called by muse, mutect2, varscan2
- HCN1 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV57528161; called by muse, varscan2
- HDAC4 | c.2755G>A p.A919T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771662328, COSV100614188; called by muse, varscan2
- HEATR5B | c.2615C>T p.A872V | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1158767769, COSV51849694; called by muse, mutect2, varscan2
- HECW1 | c.1340A>G p.K447R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV101224260; called by muse, mutect2
- HELB | c.2716C>T p.R906C | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs139082430, COSV56072243; called by muse, mutect2, varscan2
- HIVEP1 | c.8084G>A p.R2695Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1475339408, COSV101045708; called by muse, mutect2, varscan2
- HOOK2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs775716571, COSV99317831; called by muse, varscan2
- HOXA1 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as rs764729360, COSV56067101; called by muse, varscan2
- HRNR | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 66/177 reads (37%) | catalogued as rs181939236, COSV64254333, COSV64260136; called by muse, mutect2, varscan2
- HTR5A | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.219); catalogued as rs781248866, COSV99839962; called by muse, mutect2, varscan2
- HTT | c.6250G>A p.G2084R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs780493120, COSV100751224; called by muse, mutect2, varscan2
- HYAL2 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.253); catalogued as rs782471279, COSV99222872; called by muse, mutect2, varscan2
- IARS1 | c.3089C>T p.T1030I | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV100986676, COSV65113577; called by muse, mutect2, varscan2
- IARS2 | c.1675C>T p.Q559* | Nonsense Mutation (SNP) | VAF 24/61 reads (39%) | catalogued as COSV100228602; called by muse, mutect2, varscan2
- IDE | c.1706del p.L569Cfs*45 | Frame Shift Del (DEL) | VAF 38/79 reads (48%) | catalogued as rs771790236; called by mutect2, varscan2
- IFI44 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV66074647; called by muse, mutect2, varscan2
- IFITM5 | c.306del p.L103Wfs*3 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | catalogued as rs778475442; called by mutect2, pindel, varscan2
- IGSF9 | c.154del p.L52Cfs*79 | Frame Shift Del (DEL) | VAF 29/103 reads (28%) | catalogued as rs753928344; called by mutect2, pindel, varscan2
- IGSF9B | c.2473C>T p.R825W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs776267595, COSV58069204; called by muse, mutect2, varscan2
- IHO1 | c.547C>G p.Q183E | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs769207734, COSV99606491; called by muse, mutect2, varscan2
- IL13 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs201475069, COSV58733981; called by muse, mutect2, varscan2
- IL13RA1 | c.1107G>A p.R369= | Splice Region (SNP) | VAF 46/108 reads (43%) | catalogued as COSV100861583; called by muse, mutect2, varscan2
- IL17RC | c.1111C>A p.L371I (on ENST00000295981 / NM_153461.4; = p.L285I on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.341); catalogued as COSV99926004; called by muse, mutect2
- IL1RAPL2 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61150217; called by muse, mutect2, varscan2
- INKA2 | c.559del p.A187Hfs*20 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs751997684, COSV61878369; called by mutect2, pindel, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs760925109; called by mutect2, varscan2
- IQCG | c.977G>T p.R326M | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as COSV99502688; called by muse, mutect2, varscan2
- IRS4 | c.1772del p.G591Afs*20 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs780982673; called by mutect2, varscan2
- ITGB4 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as rs749456201, COSV99564710; called by muse, mutect2, varscan2
- ITIH6 | c.2582C>A p.P861Q | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV99029265; called by muse, mutect2, varscan2
- ITPR2 | c.7360A>G p.K2454E | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV101190153; called by muse, mutect2, varscan2
- KANK1 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100620088; called by muse, mutect2, varscan2
- KANK2 | c.2093A>G p.N698S (on ENST00000586659 / NM_001379562.1; = p.N706S on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100763380; called by muse, mutect2, varscan2
- KANSL3 | c.2149T>C p.S717P (on ENST00000666923 / NM_001349262.2; = p.S691P on NM_001115016.3) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV100831243; called by muse, mutect2, varscan2
- KBTBD2 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs756027234, COSV100406588; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNG4 | c.26del p.G9Afs*49 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | catalogued as rs764627943; called by mutect2, pindel
- KCNV1 | c.1195A>G p.R399G | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.921); catalogued as rs772986756, COSV99819420; called by muse, mutect2, varscan2
- KDF1 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1306424911, COSV100264652; called by muse, mutect2
- KDM4B | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99347398; called by muse, mutect2, varscan2
- KIAA1614 | c.2738C>T p.P913L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs746230529, COSV100851240; called by muse, varscan2
- KIAA1958 | c.2015G>T p.R672M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV100516448; called by muse, mutect2, varscan2
- KIF18B | c.928C>A p.R310S | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100192572, COSV100192699; called by muse, mutect2, varscan2
- KIF24 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs773813925, COSV100799331; called by muse, mutect2, varscan2
- KIF7 | c.2552G>A p.R851H | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs750613716, COSV67999843; called by muse, mutect2, varscan2
- KIFAP3 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs1334698174, COSV100847153; called by muse, mutect2, varscan2
- KMT2B | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 62/127 reads (49%) | catalogued as COSV52892583; called by muse, mutect2, varscan2
- KNTC1 | c.5858del p.N1953Tfs*9 | Frame Shift Del (DEL) | VAF 21/62 reads (34%) | catalogued as COSV100338915; called by mutect2, pindel, varscan2
- KRT25 | c.219del p.L74Sfs*8 | Frame Shift Del (DEL) | VAF 70/186 reads (38%) | catalogued as rs1287996756; called by mutect2, pindel, varscan2
- KXD1 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs61763054; called by muse, mutect2, varscan2
- LACTB | c.1240A>G p.M414V | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as rs1418566096, COSV99979057; called by muse, mutect2, varscan2
- LAMA5 | c.9289C>A p.L3097M | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as COSV99442141; called by muse, mutect2, varscan2
- LAMA5 | c.4906C>T p.R1636C | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs771601969, COSV99442147; called by muse, mutect2, varscan2
- LARP6 | c.722del p.P241Lfs*36 | Frame Shift Del (DEL) | VAF 28/65 reads (43%) | catalogued as COSV54581501; called by mutect2, pindel, varscan2
- LCK | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs527608634, COSV60740747, COSV60741826; called by muse, mutect2, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 18/58 reads (31%) | catalogued as rs765287063; called by mutect2, varscan2
- LMO7 | c.765dup p.R256Afs*2 (on ENST00000357063; = p.R271Afs*2 on NM_005358.5) | Frame Shift Ins (INS) | VAF 35/101 reads (35%) | catalogued as rs1186671184; called by mutect2, pindel, varscan2
- LONRF1 | c.1898C>T p.P633L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs773002986, COSV68037100; called by muse, mutect2, varscan2
- LPA | c.3287C>T p.A1096V | Missense Mutation (SNP) | VAF 215/489 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs375355500; called by muse, mutect2, varscan2
- LPCAT3 | c.1120C>T p.H374Y | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99781299; called by muse, mutect2, varscan2
- LRG1 | c.543dup p.G182Rfs*13 | Frame Shift Ins (INS) | VAF 28/92 reads (30%) | catalogued as rs34044863; called by mutect2, pindel, varscan2
- LRRC45 | c.1047+1G>A p.X349_splice | Splice Site (SNP) | VAF 12/223 reads (5%) | catalogued as rs960988930; called by muse, mutect2
- LRRC4C | c.433G>C p.V145L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV99539637; called by muse, mutect2, varscan2
- LRRC8A | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.377); catalogued as rs1433723247, COSV99396762, COSV99396820; called by muse, mutect2
- LURAP1 | c.614G>T p.R205M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.163); catalogued as COSV100915086; called by muse, mutect2, varscan2
- MAGIX | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV100891923; called by muse, mutect2, varscan2
- MAGT1 | c.190C>A p.L64I (on ENST00000618282 / NM_001367916.1; = p.L96I on NM_032121.5) | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV100800433; called by muse, mutect2, varscan2
- MAOB | c.915C>A p.F305L | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100956232; called by muse, mutect2, varscan2
- MAP2 | c.830A>G p.E277G | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.994); catalogued as COSV99561614; called by muse, mutect2, varscan2
- MAP3K12 | c.1009G>T p.D337Y | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99913538; called by muse, mutect2, varscan2
- MAP3K6 | c.3781C>T p.R1261C | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs111630918, COSV58873738; called by muse, mutect2, varscan2
- MARCHF7 | c.886del p.S296Hfs*9 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs1383130845; called by mutect2, varscan2
- MBD1 | c.1445A>G p.Q482R (on ENST00000269468 / NM_001323950.1; = p.Q426R on NM_002384.2) | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.795); catalogued as rs1216045290, COSV99497185; called by muse, mutect2, varscan2
- MED12 | c.4093C>T p.L1365F | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as COSV100379833; called by muse, mutect2, varscan2
- MEFV | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99561259; called by muse, mutect2, varscan2
- MEPE | c.1177A>G p.S393G | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV100734993; called by muse, mutect2, varscan2
- MICAL1 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs577273855, COSV62192316; called by muse, mutect2, varscan2
- MIDEAS | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs757966332, COSV99679040, COSV99679223; called by muse, mutect2, varscan2
- MIS18BP1 | c.471del p.K157Nfs*24 | Frame Shift Del (DEL) | VAF 50/116 reads (43%) | catalogued as rs546807245; called by mutect2, varscan2
- MKI67 | c.6266C>T p.T2089I | Missense Mutation (SNP) | VAF 89/208 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs1419967518, COSV100896962; called by muse, mutect2, varscan2
- MKI67 | c.698del p.N233Mfs*12 | Frame Shift Del (DEL) | VAF 21/48 reads (44%) | catalogued as rs749903408; called by mutect2, varscan2
- MLXIP | c.2651C>T p.T884M | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs528028662, COSV59836738; called by muse, mutect2, varscan2
- MOB1B | c.567del p.F189Lfs*19 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | catalogued as rs778232663; called by mutect2, varscan2
- MRPL19 | c.83del p.P28Rfs*49 | Frame Shift Del (DEL) | VAF 63/174 reads (36%) | catalogued as rs1558718327, COSV62567684; called by mutect2, pindel, varscan2
- MRPS11 | c.469G>T p.G157* | Nonsense Mutation (SNP) | VAF 53/151 reads (35%) | catalogued as COSV57915270; called by muse, mutect2, varscan2
- MRPS30 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs61753790, COSV99138180; called by muse, varscan2
- MTG1 | c.380C>T p.T127I | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1279762334, COSV100448939; called by muse, mutect2
- MTMR3 | c.3344G>A p.R1115H | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs754896200, COSV100071337; called by muse, mutect2, varscan2
- MUTYH | c.435C>A p.Y145* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100588174; called by muse, mutect2, varscan2
- MYBL2 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99406716; called by muse, mutect2, varscan2
- MYCBP2 | c.6745A>G p.I2249V (on ENST00000357337; = p.I2287V on NM_015057.5) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100630190; called by muse, mutect2, varscan2
- MYH3 | c.2267A>G p.Q756R | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV56860561, COSV99878833; called by muse, mutect2, varscan2
- MYH7 | c.4012C>T p.H1338Y | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV100806592; called by muse, mutect2, varscan2
- MYH7B | c.2305C>T p.R769W | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746101675, COSV53417958; called by muse, mutect2, varscan2
- MYLIP | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.767); catalogued as COSV100786030; called by muse, mutect2, varscan2
- MYO10 | c.2914G>A p.A972T | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99946226, COSV99946391; called by muse, mutect2, varscan2
- MYO18A | c.3412C>T p.R1138C | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs759164088, COSV100572700; called by muse, mutect2, varscan2
- MYO1B | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100270026, COSV100270123; called by muse, mutect2, varscan2
- MYOM3 | c.3929G>T p.G1310V | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100141967; called by muse, mutect2
- MYOZ2 | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.057); catalogued as COSV100201853; called by muse, mutect2, varscan2
- NASP | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.183); catalogued as rs779995067, COSV100601997; called by muse, mutect2
- NAV3 | c.5297C>T p.A1766V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.137); catalogued as rs768748970, COSV99890417, COSV99893896; called by muse, mutect2, varscan2
- NCAPD2 | c.2508dup p.F837Lfs*11 | Frame Shift Ins (INS) | VAF 42/121 reads (35%) | catalogued as rs772347389; called by mutect2, varscan2
- NCKIPSD | c.172-3dup | Splice Region (INS) | VAF 22/54 reads (41%) | catalogued as rs768132931; called by mutect2, varscan2
- NCOA7 | c.2692G>T p.G898W | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99997628; called by muse, mutect2
- NCOR2 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1417901373, COSV62295930; called by muse, mutect2, varscan2
- NEB | c.11512G>T p.D3838Y | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99415127; called by muse, mutect2, varscan2
- NEDD4 | c.1555G>T p.D519Y (on ENST00000508342 / NM_001284338.1; = p.D100Y on NM_006154.4) | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100164093; called by muse, mutect2, varscan2
- NEK1 | c.1813dup p.I605Nfs*28 | Frame Shift Ins (INS) | VAF 29/73 reads (40%) | catalogued as rs1461849431; called by mutect2, varscan2
- NENF | c.342+1G>A p.X114_splice | Splice Site (SNP) | VAF 28/71 reads (39%) | catalogued as rs113560940, COSV100877100; called by muse, mutect2, varscan2
- NEURL4 | c.3841G>A p.D1281N | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1471263370, COSV100223303; called by muse, mutect2, varscan2
- NHS | c.1456C>A p.L486I | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101196957; called by muse, mutect2, varscan2
- NID1 | c.2891T>C p.M964T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99938279; called by muse, mutect2, varscan2
- NID2 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99357214; called by muse, mutect2
- NINL | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV54000416, COSV99626257; called by muse, mutect2
- NKTR | c.3905C>T p.T1302M | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs773037322, COSV99236315; called by muse, varscan2
- NOTCH1 | c.2270G>A p.C757Y | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99491513; called by muse, mutect2, varscan2
- NPBWR1 | c.67T>C p.C23R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100488300; called by muse, mutect2, varscan2
- NPEPL1 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as rs535099373, COSV100622583; called by muse, mutect2, varscan2
- NR1H2 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 57/137 reads (42%) | catalogued as COSV99516532; called by muse, mutect2, varscan2
- NRSN2 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs372152096; called by muse, mutect2, varscan2
- NT5DC1 | c.338C>G p.S113W | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs757924218, COSV100127150, COSV100127238; called by muse, varscan2
- NTMT1 | c.163-2A>G p.X55_splice | Splice Site (SNP) | VAF 45/111 reads (41%) | catalogued as COSV99475843; called by muse, mutect2, varscan2
- NUP210 | c.2044G>A p.V682I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs149471357; called by muse, mutect2
- NUP214 | c.2446C>T p.R816C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1318785562, COSV100845385; called by muse, mutect2, varscan2
- NWD1 | c.2458G>A p.A820T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as rs139109286; called by muse, mutect2, varscan2
- NXN | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100403483; called by muse, mutect2, varscan2
- NYNRIN | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as COSV101230697, COSV66842833; called by muse, mutect2, varscan2
- OBSCN | c.12193G>T p.V4065F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV99478358, COSV99484025; called by muse, mutect2, varscan2
- OBSCN | c.21334G>C p.G7112R | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs556531467, COSV100805452; called by muse, varscan2
- ODF3 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs149763715; called by muse, mutect2, varscan2
- OMA1 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100678380; called by muse, varscan2
- OPN4 | c.794C>T p.T265I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs781122616, COSV99618808; called by muse, mutect2, varscan2
- OR14C36 | c.416G>A p.C139Y | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100507645; called by muse, mutect2, varscan2
- OR2B11 | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100276617; called by muse, mutect2, varscan2
- OR51I2 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100413474; called by muse, mutect2, varscan2
- OR9Q2 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs746060364, COSV61111404; called by muse, mutect2, varscan2
- P3H2 | c.1358T>C p.V453A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs1475596727, COSV100078443; called by muse, mutect2, varscan2
- PAK6 | c.1782G>T p.M594I | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99545018; called by muse, mutect2
- PANX3 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs267602763, COSV99421084; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 32/87 reads (37%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PBX2 | c.1042A>G p.N348D | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.194); catalogued as COSV100904062; called by mutect2, varscan2
- PC | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs769250651, COSV67371964; called by muse, mutect2, varscan2
- PCARE | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100527525; called by muse, mutect2, varscan2
- PCDH10 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52091129; called by muse, mutect2, varscan2
- PCDHB11 | c.1348A>G p.T450A | Missense Mutation (SNP) | VAF 80/352 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs61739364, COSV61312656; called by muse, mutect2, varscan2
- PCDHB14 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 150/369 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.202); catalogued as COSV99506255; called by muse, mutect2, varscan2
- PCDHB6 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 98/246 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50733864; called by muse, mutect2, varscan2
- PCDHB6 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 14/383 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV50694563; called by muse, mutect2
- PCDHGA5 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.22); catalogued as rs532159175, COSV99546391; called by muse, mutect2, varscan2
- PCOLCE | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV99575658; called by muse, mutect2, varscan2
- PCOLCE | c.1173del p.M392* | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs777844367; called by mutect2, pindel, varscan2
- PDE3B | c.2567C>T p.A856V | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56389750; called by muse, mutect2, varscan2
- PDIA3 | c.302C>A p.P101Q | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100295290; called by muse, mutect2, varscan2
- PDZD2 | c.3322del p.Q1108Sfs*17 | Frame Shift Del (DEL) | VAF 22/48 reads (46%) | catalogued as rs1212611383; called by mutect2, varscan2
- PGD | c.1211A>G p.D404G | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.09); catalogued as COSV99581711; called by muse, mutect2, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHF1 | c.1628G>T p.R543L | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99538967; called by muse, mutect2, varscan2
- PIGB | c.529dup p.C177Lfs*79 | Frame Shift Ins (INS) | VAF 64/162 reads (40%) | catalogued as rs1356026422; called by mutect2, varscan2
- PITPNM3 | c.409G>T p.G137* | Nonsense Mutation (SNP) | VAF 33/82 reads (40%) | catalogued as COSV99339045; called by muse, mutect2, varscan2
- PKHD1 | c.2715+1G>A p.X905_splice | Splice Site (SNP) | VAF 10/139 reads (7%) | catalogued as COSV100584497; called by muse, mutect2
- PKHD1L1 | c.9216G>A p.M3072I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV65742180; called by muse, mutect2, varscan2
- PLA2G4D | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs1177601143, COSV99300027; called by muse, mutect2, varscan2
- PLCB4 | c.3505C>T p.R1169C (on ENST00000278655 / NM_182797.3; = p.P1181L on NM_000933.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.336); catalogued as rs1188180544, COSV53805537, COSV99597126; called by muse, mutect2, varscan2
- PLEKHH3 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.805); catalogued as COSV53188226; called by muse, mutect2, varscan2
- PLIN4 | c.1006G>T p.G336* (on ENST00000301286; = p.G351* on NM_001367868.2) | Nonsense Mutation (SNP) | VAF 71/118 reads (60%) | catalogued as COSV100014095; called by muse, mutect2, varscan2
- PLPPR3 | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100609074; called by muse, mutect2
- PLXNB1 | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.149); catalogued as rs374413275, COSV56491225; called by muse, mutect2, varscan2
- PNPLA6 | c.2005G>A p.V669M (on ENST00000414982 / NM_001166111.2; = p.V621M on NM_006702.5) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV55374098; called by muse, mutect2, varscan2
- POU3F4 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV100937178, COSV100937244; called by muse, mutect2, varscan2
- PPFIBP1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765962629, COSV99945394; called by muse, mutect2, varscan2
- PPHLN1 | c.1024+7G>A | Splice Region (SNP) | VAF 21/136 reads (15%) | catalogued as rs780049555, COSV56737605; called by muse, mutect2, varscan2
- PPM1D | c.1349dup p.L450Ffs*6 | Frame Shift Ins (INS) | VAF 32/96 reads (33%) | catalogued as rs758630849; called by mutect2, pindel, varscan2
- PPP1R12A | c.1619del p.N540Ifs*23 | Frame Shift Del (DEL) | VAF 40/102 reads (39%) | catalogued as rs776166170; called by mutect2, varscan2
- PPP1R12B | c.1736C>A p.P579Q | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV100408425; called by muse, mutect2, varscan2
- PRADC1 | c.187A>T p.I63F | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99240361; called by muse, mutect2, varscan2
- PRDM15 | c.2477C>T p.A826V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1340125947, COSV99520943; called by muse, mutect2, varscan2
- PRDM5 | c.132G>A p.M44I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV53362068, COSV99311356; called by muse, mutect2, varscan2
- PRICKLE3 | c.237C>A p.H79Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.18); catalogued as COSV99603095; called by muse, mutect2, varscan2
- PRKCI | c.826del p.T276Qfs*7 | Frame Shift Del (DEL) | VAF 36/106 reads (34%) | catalogued as rs753143066; called by mutect2, varscan2
- PRPF31 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs150280707; called by muse, mutect2, varscan2
- PRPF8 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100517872; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 25/68 reads (37%) | catalogued as rs753236928; called by mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 44/118 reads (37%) | catalogued as rs781858060; called by mutect2, varscan2
- PRSS38 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT tolerated (0.74); PolyPhen benign (0.015); catalogued as rs188432918, COSV64539931; called by muse, mutect2, varscan2
- PSMB11 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as rs746331247, COSV68430492; called by muse, mutect2, varscan2
- PSMC3IP | c.206_208del p.K69del | In Frame Del (DEL) | VAF 38/95 reads (40%) | catalogued as rs1343591413; called by pindel, varscan2
- PTPRM | c.1441+1G>A p.X481_splice | Splice Site (SNP) | VAF 24/64 reads (38%) | catalogued as COSV100160222; called by muse, mutect2, varscan2
- PTPRS | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53615850; called by muse, mutect2, varscan2
- PTPRT | c.3224del p.P1075Rfs*6 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs1568940954, COSV62005004; called by mutect2, pindel, varscan2
- PUF60 | c.371C>T p.A124V (on ENST00000526683 / NM_001362896.2; = p.A107V on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs749670489, COSV100254082; called by muse, mutect2, varscan2
- PUM2 | c.1595G>T p.S532I | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as COSV100163619; called by muse, mutect2, varscan2
- PWWP2B | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as rs765792317, COSV59452747; called by muse, mutect2, varscan2
- RAB3GAP1 | c.1388_1389del p.C463Sfs*24 | Frame Shift Del (DEL) | VAF 47/155 reads (30%) | catalogued as rs1282248700; called by pindel, varscan2
- RAP1GAP2 | c.1103A>G p.N368S | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV99624307; called by muse, mutect2, varscan2
- RBM10 | c.432+1G>A p.X144_splice | Splice Site (SNP) | VAF 48/114 reads (42%) | catalogued as rs782679832, COSV61313119; called by muse, mutect2, varscan2
- RDX | c.1412del p.P471Lfs*35 | Frame Shift Del (DEL) | VAF 65/173 reads (38%) | catalogued as COSV100563010; called by mutect2, pindel, varscan2
- REV3L | c.5081del p.N1694Mfs*4 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | catalogued as COSV62617292; called by mutect2, pindel, varscan2
- REV3L | c.2917C>A p.P973T | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100725672; called by muse, mutect2, varscan2
- RGS4 | c.476T>C p.L159P | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63357723; called by muse, mutect2, varscan2
- RHPN1 | c.1461del p.K488Rfs*29 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs1228467803; called by mutect2, pindel, varscan2
- RIMKLA | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.08); catalogued as COSV101343485; called by muse, mutect2, varscan2
- RIN1 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs755515350, COSV100254980; called by muse, varscan2
- RNASEL | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV100842644; called by muse, mutect2
- RNF169 | c.1420_1422del p.E474del | In Frame Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs1377257612; called by mutect2, varscan2
- RNF207 | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | catalogued as COSV100933764; called by muse, mutect2
- RNF25 | c.749dup p.I251Nfs*3 | Frame Shift Ins (INS) | VAF 16/36 reads (44%) | catalogued as rs746813141; called by mutect2, varscan2
- RNF43 | c.1976dup p.P660Sfs*87 | Frame Shift Ins (INS) | VAF 30/86 reads (35%) | catalogued as rs755128667; called by mutect2, varscan2
- RNF6 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs745325624, COSV60417848; called by muse, mutect2, varscan2
- RPH3A | c.1355G>A p.R452Q (on ENST00000389385 / NM_001143854.2; = p.R448Q on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs767497432, COSV66991337, COSV66991418; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 29/71 reads (41%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA6 | c.663G>T p.K221N | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99425409; called by muse, mutect2, varscan2
- RSPH6A | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs775123898, COSV99680096; called by muse, varscan2
- RTN2 | c.178del p.R60Gfs*3 | Frame Shift Del (DEL) | VAF 38/103 reads (37%) | catalogued as COSV55595576; called by mutect2, pindel, varscan2
- RXRA | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV100709360; called by muse, mutect2, varscan2
- RYR2 | c.13804C>T p.R4602* | Nonsense Mutation (SNP) | VAF 29/61 reads (48%) | catalogued as rs878853077, COSV63670601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCAF8 | c.2951del p.L984* | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | catalogued as COSV65790894; called by mutect2, pindel, varscan2
- SCAPER | c.2613del p.A872Pfs*4 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | catalogued as rs757259031; called by mutect2, varscan2
- SCML2 | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52619167; called by muse, mutect2, varscan2
- SDF2 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV99898017; called by muse, mutect2, varscan2
- SERPINF1 | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99628959; called by muse, mutect2
- SGSM3 | c.1324G>A p.V442M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs202226045; called by muse, varscan2
- SH2D3A | c.1697G>A p.G566D | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99837729; called by muse, mutect2, varscan2
- SH3BP5 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs759847333, COSV53745424; called by muse, mutect2
- SHKBP1 | c.1483A>G p.N495D | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV99199512; called by muse, mutect2, varscan2
- SHROOM2 | c.4466G>A p.R1489Q | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs376434792, COSV66604612; called by muse, mutect2, varscan2
- SIRPB1 | c.838del p.R280Gfs*5 | Frame Shift Del (DEL) | VAF 63/198 reads (32%) | catalogued as COSV99498551; called by mutect2, pindel, varscan2
- SLC20A2 | c.1471C>T p.Q491* | Nonsense Mutation (SNP) | VAF 42/83 reads (51%) | catalogued as COSV100646215; called by muse, mutect2, varscan2
- SLC26A1 | c.641G>A p.G214D | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765995686, COSV99926433; called by muse, mutect2, varscan2
- SLC26A8 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV100839606; called by muse, mutect2, varscan2
- SLC2A5 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs368743770, COSV66235920; called by muse, mutect2, varscan2
- SLC30A10 | c.719-2A>G p.X240_splice | Splice Site (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100751593; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC52A1 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV99643525; called by muse, mutect2, varscan2
- SLC6A1 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55114429, COSV99822925; called by muse, mutect2, varscan2
- SLC9A3R2 | c.259G>C p.V87L | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1183574603, COSV70165809; called by muse, mutect2, varscan2
- SLCO6A1 | c.1897T>C p.S633P | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV101134947; called by muse, mutect2, varscan2
- SLU7 | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.703); catalogued as COSV99775820; called by muse, mutect2, varscan2
- SMARCC1 | c.2113G>A p.V705M | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV99593448; called by muse, mutect2, varscan2
- SMC4 | c.1272G>T p.K424N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100644135; called by muse, mutect2, varscan2
- SMG1 | c.10508G>A p.S3503N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as COSV101246780; called by muse, mutect2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 30/70 reads (43%) | catalogued as rs768873484; called by mutect2, varscan2
- SOCS3 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100434539, COSV58270141; called by muse, mutect2, varscan2
- SOGA3 | c.1535del p.K512Rfs*14 | Frame Shift Del (DEL) | VAF 40/99 reads (40%) | catalogued as rs34142169, COSV64106882; called by mutect2, varscan2
- SORL1 | c.3811T>C p.C1271R | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763707983, COSV99495397; called by muse, mutect2, varscan2
- SORL1 | c.4442C>T p.P1481L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs544390676, COSV52751991, COSV99495400; called by muse, mutect2, varscan2
- SOS1 | c.3077G>T p.R1026I | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV101217272; called by muse, mutect2, varscan2
- SOX13 | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99690048; called by muse, mutect2, varscan2
- SP100 | c.2512C>T p.R838C | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); catalogued as rs534239970, COSV60849846; called by muse, mutect2, varscan2
- SP110 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as COSV99283799; called by muse, mutect2, varscan2
- SPAG17 | c.4637C>T p.A1546V | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100310486; called by muse, mutect2, varscan2
- SPAG9 | c.1645del p.R549Gfs*28 (on ENST00000262013 / NM_001130528.3; = p.R535Gfs*28 on NM_003971.6) | Frame Shift Del (DEL) | VAF 40/96 reads (42%) | catalogued as rs371303534; called by mutect2, varscan2
- SPATA31E1 | c.3227C>A p.P1076H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.966); catalogued as rs1203417637, COSV100351047; called by muse, mutect2, varscan2
- SPATA46 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.124); catalogued as rs372797714; called by muse, mutect2, varscan2
- SPOP | c.238A>C p.S80R | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100753583; called by muse, mutect2, varscan2
- SPSB3 | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99236688; called by muse, mutect2, varscan2
- SREK1IP1 | c.271del p.R91Gfs*67 | Frame Shift Del (DEL) | VAF 21/120 reads (18%) | catalogued as rs750306056; called by mutect2, varscan2
- SRMS | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374425555; called by muse, mutect2, varscan2
- ST14 | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99599119; called by muse, mutect2, varscan2
- ST20 | c.190A>T p.I64F | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.199); catalogued as COSV51914008; called by muse, mutect2, varscan2
- ST6GAL2 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | PolyPhen benign (0.044); catalogued as COSV100868272; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 36/106 reads (34%) | catalogued as rs752994755; called by mutect2, varscan2
- STAU2 | c.1091del p.N364Mfs*67 (on ENST00000524300 / NM_001164380.2; = p.N332Mfs*67 on NM_014393.2) | Frame Shift Del (DEL) | VAF 32/172 reads (19%) | catalogued as rs746501298; called by mutect2, varscan2
- STRA6 | c.575C>A p.A192E | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100121288; called by muse, mutect2, varscan2
- STS | c.259+1G>T p.X87_splice | Splice Site (SNP) | VAF 27/78 reads (35%) | catalogued as COSV99481637; called by muse, mutect2, varscan2
- SURF4 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100915255, COSV64339193; called by muse, mutect2, varscan2
- SYBU | c.1714C>T p.R572C (on ENST00000276646 / NM_001099754.2; = p.R571C on NM_017786.6) | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs981215577, COSV99406622; called by muse, mutect2, varscan2
- SYMPK | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs770888957, COSV55616284; called by muse, mutect2, varscan2
- SYNCRIP | c.854dup p.N285Kfs*8 | Frame Shift Ins (INS) | VAF 30/81 reads (37%) | catalogued as rs1562086177; called by mutect2, varscan2
- SYNDIG1 | c.553A>G p.S185G | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV100965423; called by muse, mutect2, varscan2
- SYT2 | c.35T>C p.I12T | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1237676550, COSV100937197; called by muse, mutect2, varscan2
- SYTL1 | c.1513C>T p.R505C (on ENST00000543823; = p.R493C on NM_032872.3) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs374034129; called by muse, mutect2, varscan2
- SZT2 | c.9755C>T p.A3252V (on ENST00000634258 / NM_001365999.1; = p.A3195V on NM_015284.4) | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.957); catalogued as COSV100981338; called by muse, mutect2, varscan2
- TAF3 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201464808, COSV100720108; called by muse, mutect2, varscan2
- TAS2R10 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.738); catalogued as COSV99555636; called by muse, mutect2, varscan2
- TBC1D10B | c.1826T>C p.L609P | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.296); catalogued as rs1178083988, COSV99977225; called by muse, mutect2, varscan2
- TBC1D25 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV100952225; called by muse, mutect2, varscan2
- TBC1D4 | c.3401G>A p.C1134Y | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.941); catalogued as COSV100884801; called by muse, mutect2, varscan2
- TBC1D8 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as rs553945266, COSV65211332; called by muse, mutect2, varscan2
- TBCCD1 | c.1281G>T p.E427D | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV100112145; called by muse, mutect2, varscan2
- TBCD | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as rs371619945; called by muse, mutect2, varscan2
- TENM1 | c.7262C>T p.A2421V | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV100950876; called by muse, mutect2, varscan2
- THEM5 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs772424639, COSV100917282; called by muse, mutect2, varscan2
- THRB | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 78/201 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); catalogued as rs886044192, COSV100726241; ClinVar: uncertain significance; called by muse, varscan2
- TIGD4 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100427974; called by muse, mutect2, varscan2
- TLE4 | c.2254G>A p.V752M | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.261); catalogued as rs759437087, COSV99513118; called by muse, mutect2, varscan2
- TMCO4 | c.1555G>T p.G519C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99230452; called by muse, mutect2
- TMEM184A | c.105G>T p.M35I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV52475256, COSV99868786; called by muse, mutect2, varscan2
- TMEM225 | c.587G>A p.C196Y | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs199672889, COSV100902884; called by muse, mutect2, varscan2
- TMEM47 | c.383G>A p.C128Y | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99327904; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 48/100 reads (48%) | catalogued as rs749773249; called by mutect2, varscan2
- TNFRSF10D | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs747563213, COSV100441908; called by muse, mutect2, varscan2
- TNFRSF1A | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV99164936; called by muse, mutect2, varscan2
- TNFRSF1A | c.740-1G>T p.X247_splice | Splice Site (SNP) | VAF 15/45 reads (33%) | catalogued as COSV99164937; called by muse, mutect2, varscan2
- TNPO2 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 32/80 reads (40%) | catalogued as COSV100790411; called by muse, mutect2, varscan2
- TNS3 | c.731G>A p.C244Y | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100236354; called by muse, mutect2, varscan2
- TONSL | c.1401G>T p.E467D | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.272); catalogued as COSV101340309; called by muse, mutect2
- TOX2 | c.1058C>T p.A353V (on ENST00000358131 / NM_001098798.2; = p.A329V on NM_032883.3) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as COSV100364608; called by muse, mutect2, varscan2
- TPCN1 | c.1797-1G>A p.X599_splice | Splice Site (SNP) | VAF 40/86 reads (47%) | catalogued as COSV100137055; called by muse, mutect2, varscan2
- TRAP1 | c.1283A>G p.D428G | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.351); catalogued as rs764283922, COSV99893944; called by muse, mutect2, varscan2
- TRIM11 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1237385216, COSV99488959; called by muse, mutect2, varscan2
- TRIM26 | c.91T>G p.C31G | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101359513; called by muse, mutect2, varscan2
- TRIM41 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs777223037, COSV100163260; called by muse, varscan2
- TRIM46 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs778912457, COSV100583780; called by muse, mutect2, varscan2
- TRIM71 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV67471016; called by muse, mutect2, varscan2
- TRIO | c.1118G>A p.S373N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100710935; called by muse, mutect2, varscan2
- TRIP11 | c.2248C>T p.R750C | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs781736512, COSV99971159; called by muse, mutect2, varscan2
- TRMU | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs769241192, COSV99324701; called by muse, mutect2, varscan2
- TRPV2 | c.1329del p.I444Sfs*23 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as COSV100641106; called by mutect2, varscan2
- TSHR | c.2159A>G p.Q720R | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV99992797; called by muse, mutect2, varscan2
- TSSK1B | c.1075del p.Q359Nfs*43 | Frame Shift Del (DEL) | VAF 23/90 reads (26%) | catalogued as rs747842861, COSV101181233; called by mutect2, pindel, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | catalogued as rs756650873; called by mutect2, varscan2
- TTC32 | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100367832; called by muse, mutect2, varscan2
- TTF1 | c.1007dup p.K337Efs*9 | Frame Shift Ins (INS) | VAF 32/77 reads (42%) | catalogued as rs772401251; called by mutect2, varscan2
- TTI1 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV100989748; called by muse, mutect2, varscan2
- TUB | c.747G>T p.Q249H (on ENST00000299506 / NM_177972.3; = p.Q304H on NM_003320.4) | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100210433; called by muse, mutect2, varscan2
- UBA52 | c.77T>C p.V26A | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV99723728; called by muse, mutect2, varscan2
- UGT2B4 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 136/309 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as rs1314997496, COSV59316881; called by muse, mutect2, varscan2
- ULBP3 | c.700C>A p.L234I | Missense Mutation (SNP) | VAF 102/259 reads (39%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.726); catalogued as COSV100949660; called by muse, mutect2, varscan2
- UNC13A | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs774523027, COSV53191198; called by muse, mutect2, varscan2
- USH1G | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs745713548, COSV100140565, COSV100140626; called by muse, mutect2, varscan2
- USH2A | c.14313C>A p.F4771L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV56456601; called by muse, mutect2, varscan2
- USO1 | c.770A>G p.Q257R | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.238); catalogued as COSV53707650; called by muse, mutect2, varscan2
- USP2 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as rs946534723, COSV99489962; called by muse, mutect2, varscan2
- USP34 | c.9079C>T p.R3027* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | catalogued as COSV101277204; called by muse, mutect2, varscan2
- USP35 | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776819918, COSV101489136; called by muse, mutect2, varscan2
- USP42 | c.1565T>A p.I522N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.254); catalogued as COSV100084874; called by muse, varscan2
- UVRAG | c.709del p.S237Vfs*6 | Frame Shift Del (DEL) | VAF 36/76 reads (47%) | catalogued as rs762976381; called by mutect2, varscan2
- VPS13A | c.2593C>T p.R865* | Nonsense Mutation (SNP) | VAF 36/93 reads (39%) | catalogued as rs766404788, CM022627, COSV100653488; called by muse, mutect2, varscan2
- VPS9D1 | c.1589A>G p.E530G | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV101232040; called by muse, mutect2, varscan2
- VRK2 | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100418243; called by muse, mutect2, varscan2
- WARS2 | c.887G>A p.G296D | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV99346747; called by muse, mutect2, varscan2
- WDR45B | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs1238810423, COSV101124468; called by muse, mutect2, varscan2
- WWC3 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs779066758, COSV66502165; called by muse, mutect2, varscan2
- XDH | c.1360C>A p.L454I | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.092); catalogued as COSV101052462; called by muse, mutect2, varscan2
- XIRP1 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.116); catalogued as rs189373113; called by muse, varscan2
- XPR1 | c.1373T>C p.L458P | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV100851516; called by muse, mutect2, varscan2
- XYLT1 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757356673, COSV54477491; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs779864368; called by mutect2, varscan2
- ZBED1 | c.1796C>A p.P599H | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100586053, COSV58137221; called by muse, mutect2, varscan2
- ZBED8 | c.1659T>A p.H553Q | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.167); catalogued as COSV101283551; called by muse, mutect2, varscan2
- ZFHX3 | c.5774del p.G1925Vfs*72 | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | catalogued as COSV51735242; called by mutect2, pindel, varscan2
- ZFP36 | c.140G>A p.S47N (on ENST00000594442; = p.S41N on NM_003407.5) | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs776166452, COSV99953986; called by muse, mutect2, varscan2
- ZFYVE28 | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs776520321, COSV99343634; called by muse, varscan2
- ZMIZ1 | c.3158C>T p.P1053L | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1300598426, COSV100566531; called by muse, mutect2, varscan2
- ZNF207 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.993); catalogued as rs770683256, COSV100340681; called by muse, mutect2, varscan2
- ZNF222 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 128/275 reads (47%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.924); catalogued as rs769496578, COSV99496614; called by muse, mutect2, varscan2
- ZNF229 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.922); catalogued as COSV99350917; called by muse, mutect2, varscan2
- ZNF34 | c.664dup p.T222Nfs*6 | Frame Shift Ins (INS) | VAF 24/70 reads (34%) | catalogued as rs751927309; called by mutect2, varscan2
- ZNF347 | c.491C>T p.T164I | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs1299782446, COSV100498426; called by muse, mutect2, varscan2
- ZNF43 | c.516dup p.L173Tfs*21 | Frame Shift Ins (INS) | VAF 42/105 reads (40%) | catalogued as rs748612562; called by mutect2, varscan2
- ZNF48 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100198220; called by muse, mutect2, varscan2
- ZNF490 | c.812del p.N271Ifs*24 | Frame Shift Del (DEL) | VAF 21/51 reads (41%) | catalogued as rs773301575; called by mutect2, pindel, varscan2
- ZNF536 | c.183dup p.A62Rfs*184 | Frame Shift Ins (INS) | VAF 11/35 reads (31%) | catalogued as rs780280249; called by mutect2, pindel, varscan2
- ZNF576 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as rs568418404, COSV100338249; called by muse, mutect2, varscan2
- ZNF649 | c.1274C>T p.T425M | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs759358137, COSV56815156; called by muse, mutect2, varscan2
- ZNF813 | c.263A>G p.Q88R | Missense Mutation (SNP) | VAF 94/239 reads (39%) | SIFT tolerated (1); PolyPhen possibly damaging (0.754); catalogued as rs775298056, COSV101124996; called by muse, mutect2, varscan2
- ZNF829 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV101199728, COSV104430045; called by muse, mutect2, varscan2
- ZSCAN22 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.82); PolyPhen benign (0.005); catalogued as rs751963267, COSV100308287, COSV61639715; called by muse, mutect2, varscan2
- ZSCAN31 | c.1191T>A p.H397Q | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100717135; called by muse, mutect2, varscan2
- ABCC11 | c.630del p.L211Sfs*5 | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | called by mutect2, pindel, varscan2
- ACSM4 | c.14dup p.R6Pfs*6 | Frame Shift Ins (INS) | VAF 17/38 reads (45%) | called by mutect2, varscan2
- ADAMTSL4 | c.789del p.S264Hfs*6 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, varscan2
- ADD1 | c.2003del p.P668Qfs*61 | Frame Shift Del (DEL) | VAF 26/73 reads (36%) | called by mutect2, pindel, varscan2
- ADGRB1 | c.1887del p.T630Pfs*15 | Frame Shift Del (DEL) | VAF 29/87 reads (33%) | called by mutect2, pindel, varscan2
- AHNAK | c.12562del p.M4188Cfs*4 | Frame Shift Del (DEL) | VAF 133/326 reads (41%) | called by mutect2, pindel, varscan2
- AKAP11 | c.806_807del p.T269Nfs*14 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by pindel, varscan2
- ARHGEF26 | c.440del p.P147Rfs*19 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- B3GNT5 | c.1047del p.F349Lfs*8 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, varscan2
- C4orf3 | c.194del p.L65Cfs*9 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | called by mutect2, pindel, varscan2
- CARD19 | c.149del p.K50Sfs*17 | Frame Shift Del (DEL) | VAF 33/97 reads (34%) | called by mutect2, pindel, varscan2
- CCDC77 | c.490del p.C164Vfs*18 | Frame Shift Del (DEL) | VAF 28/81 reads (35%) | called by mutect2, pindel, varscan2
- CCND1 | c.877_882del p.V293_D294del | In Frame Del (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- CD300A | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.692); called by muse, mutect2
- CDC42EP3 | c.302del p.P101Rfs*26 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- CEP162 | c.2761del p.I921Ffs*15 | Frame Shift Del (DEL) | VAF 32/84 reads (38%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 35/83 reads (42%) | called by mutect2, pindel, varscan2
- CHD6 | c.7380_7381del p.P2461Lfs*48 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by pindel, varscan2
- CNGB1 | c.1435del p.L479Sfs*24 | Frame Shift Del (DEL) | VAF 49/167 reads (29%) | called by mutect2, pindel, varscan2
- CNTN4 | c.1511del p.P504Lfs*18 | Frame Shift Del (DEL) | VAF 34/81 reads (42%) | called by mutect2, pindel, varscan2
- CNTROB | c.2461del p.A821Lfs*11 | Frame Shift Del (DEL) | VAF 37/140 reads (26%) | called by mutect2, pindel, varscan2
- DHX30 | c.2899_2901del p.L967del (on ENST00000445061 / NM_138615.3; = p.L928del on NM_014966.3) | In Frame Del (DEL) | VAF 21/61 reads (34%) | called by pindel, varscan2
- DLGAP2 | c.1955del p.P652Rfs*22 | Frame Shift Del (DEL) | VAF 33/92 reads (36%) | called by mutect2, pindel, varscan2
- DNAH11 | c.13240del p.T4414Qfs*72 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- ELN | c.1713dup p.G572Wfs*15 (on ENST00000320399 / NM_001278939.1; = p.G572Wfs*20 on NM_000501.4) | Frame Shift Ins (INS) | VAF 129/379 reads (34%) | called by mutect2, pindel, varscan2
- EZHIP | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.36); called by mutect2, varscan2
- FAT4 | c.13824del p.S4609Afs*11 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- GALC | c.1884del p.K628Nfs*7 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- GID8 | c.597dup p.L200Tfs*26 | Frame Shift Ins (INS) | VAF 27/78 reads (35%) | called by mutect2, pindel, varscan2
- GNRHR | c.215del p.K72Sfs*5 | Frame Shift Del (DEL) | VAF 23/67 reads (34%) | called by mutect2, pindel, varscan2
- GRIN2A | c.4326del p.R1443Gfs*3 | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- GSR | c.307-5_328delinsCCAGGTGAATGTTGGATGTGTACCC p.X103_splice | Splice Site (DEL) | VAF 15/64 reads (23%) | called by pindel, varscan2*
- HMOX2 | c.491dup p.Q165Pfs*26 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | called by mutect2, varscan2
- IARS1 | c.1590_1591del p.S530Rfs*13 | Frame Shift Del (DEL) | VAF 13/27 reads (48%) | called by mutect2, varscan2
- ILF3 | c.1201del p.Q401Rfs*3 | Frame Shift Del (DEL) | VAF 21/49 reads (43%) | called by mutect2, varscan2
- INPP5D | c.2403del p.H801Qfs*24 (on ENST00000445964 / NM_001017915.3; = p.H800Qfs*24 on NM_005541.5) | Frame Shift Del (DEL) | VAF 33/95 reads (35%) | called by mutect2, pindel, varscan2
- IPO7 | c.473del p.N158Ifs*14 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | called by mutect2, pindel, varscan2
- ISLR2 | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 67/80 reads (84%) | called by mutect2, varscan2
- JHY | c.776del p.N259Tfs*37 | Frame Shift Del (DEL) | VAF 17/39 reads (44%) | called by mutect2, varscan2
- KIF3C | c.996del p.N333Mfs*7 | Frame Shift Del (DEL) | VAF 59/143 reads (41%) | called by mutect2, pindel, varscan2
- KMT2D | c.9265del p.V3089Wfs*30 | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | called by mutect2, pindel, varscan2
- LRP1 | c.10882del p.L3628Cfs*155 | Frame Shift Del (DEL) | VAF 30/88 reads (34%) | called by mutect2, pindel, varscan2
- MCOLN2 | c.1093del p.M365Wfs*42 | Frame Shift Del (DEL) | VAF 31/92 reads (34%) | called by mutect2, pindel, varscan2
- METAP1 | c.711del p.F237Lfs*20 | Frame Shift Del (DEL) | VAF 37/119 reads (31%) | called by mutect2, pindel, varscan2
- MOG | c.216del p.F73Sfs*29 | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | called by mutect2, pindel, varscan2
- MPC2 | c.278dup p.N93Kfs*8 | Frame Shift Ins (INS) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- MPHOSPH10 | c.810dup p.D271* | Frame Shift Ins (INS) | VAF 18/57 reads (32%) | called by mutect2, varscan2
- MYO3B | c.1231del p.H411Tfs*38 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | called by mutect2, pindel, varscan2
- NDST2 | c.148del p.L50Cfs*78 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- NGRN | c.79del p.V27Wfs*31 | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | called by mutect2, pindel, varscan2
- NKD2 | c.679del p.Q227Sfs*201 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- NRDC | c.616del p.T206Lfs*17 | Frame Shift Del (DEL) | VAF 22/126 reads (17%) | called by mutect2, varscan2
- NUMA1 | c.2408G>A p.C803Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- OR2T27 | c.174del p.M59Cfs*28 | Frame Shift Del (DEL) | VAF 17/125 reads (14%) | called by mutect2, pindel, varscan2
- PHC2 | c.657del p.A220Pfs*6 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | called by mutect2, varscan2
- PLEKHM1 | c.1944del p.E649Rfs*62 | Frame Shift Del (DEL) | VAF 29/104 reads (28%) | called by mutect2, pindel, varscan2
- PLK4 | c.1550dup p.N517Kfs*5 | Frame Shift Ins (INS) | VAF 26/67 reads (39%) | called by mutect2, pindel, varscan2
- PRRC2A | c.1277del p.P426Lfs*145 | Frame Shift Del (DEL) | VAF 17/27 reads (63%) | called by mutect2, varscan2
- PRUNE2 | c.4994del p.N1665Mfs*34 | Frame Shift Del (DEL) | VAF 41/103 reads (40%) | called by mutect2, pindel, varscan2
- RBBP6 | c.4572del p.G1525Efs*37 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, varscan2
- RBM27 | c.2488del p.R830Dfs*5 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | called by mutect2, pindel, varscan2
- RPUSD4 | c.892del p.Q298Rfs*8 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- RSPO1 | c.556del p.D186Tfs*16 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
- SCLT1 | c.1269del p.A424Qfs*6 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | called by mutect2, varscan2
- SDK1 | c.6392_6393del p.S2131* | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by pindel, varscan2
- SHANK2 | c.4184del p.P1395Lfs*43 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- SLC27A4 | c.862del p.L288Sfs*19 | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | called by mutect2, pindel, varscan2
- STIMATE | c.692del p.G231Efs*28 | Frame Shift Del (DEL) | VAF 43/138 reads (31%) | called by mutect2, pindel, varscan2
- SUOX | c.599del p.P200Lfs*4 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- TCF3 | c.1154del p.G385Vfs*9 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | called by mutect2, varscan2
- TCP1 | c.730dup p.T244Nfs*15 | Frame Shift Ins (INS) | VAF 61/148 reads (41%) | called by mutect2, pindel, varscan2
- TFAP2B | c.219del p.Y74Tfs*22 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | called by mutect2, pindel
- TFE3 | c.1445del p.G482Dfs*44 | Frame Shift Del (DEL) | VAF 47/111 reads (42%) | called by mutect2, varscan2
- THUMPD1 | c.518dup p.L173Ffs*17 | Frame Shift Ins (INS) | VAF 40/119 reads (34%) | called by mutect2, pindel, varscan2
- TIGAR | c.524del p.N175Ifs*15 | Frame Shift Del (DEL) | VAF 34/114 reads (30%) | called by mutect2, pindel, varscan2
- TNK2 | c.336del p.L114Cfs*40 | Frame Shift Del (DEL) | VAF 34/93 reads (37%) | called by mutect2, pindel, varscan2
- TNRC6B | c.3247del p.M1083Wfs*5 (on ENST00000454349 / NM_001162501.2; = p.M1030Wfs*5 on NM_015088.3) | Frame Shift Del (DEL) | VAF 40/102 reads (39%) | called by mutect2, pindel, varscan2
- TNXB | c.8942del p.P2981Lfs*9 (on ENST00000647633; = p.P2734Lfs*9 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- TP53RK | c.714del p.K238Nfs*2 | Frame Shift Del (DEL) | VAF 61/190 reads (32%) | called by mutect2, pindel, varscan2
- TRAPPC12 | c.1792del p.T598Qfs*12 | Frame Shift Del (DEL) | VAF 27/87 reads (31%) | called by mutect2, pindel, varscan2
- TRIM46 | c.1363del p.H455Ifs*32 | Frame Shift Del (DEL) | VAF 19/148 reads (13%) | called by mutect2, pindel, varscan2
- TRIP6 | c.329dup p.R111Sfs*14 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | called by mutect2, varscan2
- TRPM8 | c.52_53del p.L18Gfs*20 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by pindel, varscan2
- TTC21B | c.2080del p.M694Wfs*6 | Frame Shift Del (DEL) | VAF 31/90 reads (34%) | called by mutect2, pindel, varscan2
- UBASH3B | c.1161del p.F387Lfs*33 | Frame Shift Del (DEL) | VAF 38/113 reads (34%) | called by mutect2, pindel, varscan2
- UBB | c.570del p.D191Tfs*35 | Frame Shift Del (DEL) | VAF 51/130 reads (39%) | called by mutect2, pindel, varscan2
- ULK1 | c.1722del p.T575Rfs*72 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- UQCRC1 | c.355del p.H119Ifs*49 | Frame Shift Del (DEL) | VAF 25/57 reads (44%) | called by mutect2, pindel, varscan2
- VAX2 | c.593dup p.S199* | Frame Shift Ins (INS) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- VCPKMT | c.601dup p.I201Nfs*7 | Frame Shift Ins (INS) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
- XRN1 | c.4500del p.F1500Lfs*9 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | called by mutect2, pindel, varscan2
- YTHDF1 | c.368dup p.E125* | Frame Shift Ins (INS) | VAF 62/168 reads (37%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 39/91 reads (43%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.4326dup p.H1443Tfs*8 | Frame Shift Ins (INS) | VAF 16/34 reads (47%) | called by mutect2, varscan2
- ZFP30 | c.263del p.K88Sfs*11 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- ZNF761 | c.1452_1453del p.H484Qfs*13 | Frame Shift Del (DEL) | VAF 42/123 reads (34%) | called by mutect2, pindel, varscan2
- ABCB7 | c.2253G>A p.S751= (on ENST00000373394 / NM_001271696.3; = p.S752= on NM_004299.6) | Silent (SNP) | VAF 49/111 reads (44%) | catalogued as rs771854345, COSV53720982, COSV53724260; called by muse, mutect2, varscan2
- ACACB | c.2850C>T p.A950= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs371074254; called by muse, mutect2, varscan2
- ACTL9 | c.1023C>T p.C341= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as rs1249003885, COSV61005046; called by muse, mutect2, varscan2
- ADAMTS14 | c.2049C>T p.G683= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs372557659; called by muse, varscan2
- AGAP2 | c.2358G>A p.Q786= (on ENST00000547588 / NM_001122772.2; = p.Q450= on NM_014770.4) | Silent (SNP) | VAF 42/122 reads (34%) | catalogued as COSV99224214; called by muse, mutect2, varscan2
- AGMAT | c.609G>A p.A203= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs772056977, COSV101011816; called by muse, mutect2, varscan2
- AK8 | c.262C>T p.L88= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100049949, COSV100050518; called by muse, mutect2, varscan2
- ALPK2 | c.4464A>G p.K1488= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as COSV100864781; called by muse, mutect2
- ANKFY1 | c.1338C>T p.R446= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as rs775180647, COSV58919230; called by muse, mutect2, varscan2
- ANO10 | c.489G>A p.T163= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs770151711, COSV52736673; called by muse, mutect2
- ARHGAP33 | c.846T>G p.R282= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs1363423917, COSV99139916; called by muse, mutect2, varscan2
- B3GALNT2 | c.996T>C p.V332= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100782871; called by muse, mutect2, varscan2
- B4GALT2 | c.588C>T p.N196= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs200755993, COSV100530940; called by muse, varscan2
- BCAR1 | c.696C>T p.D232= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs201960451, COSV99367079; called by muse, mutect2, varscan2
- BCL9 | c.3414C>T p.P1138= | Silent (SNP) | VAF 44/93 reads (47%) | catalogued as rs782598148, COSV52349222, COSV99325788; called by muse, mutect2, varscan2
- BPIFB3 | c.231C>T p.G77= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as COSV64958239; called by muse, mutect2, varscan2
- C1GALT1C1 | c.918A>G p.A306= | Silent (SNP) | VAF 45/82 reads (55%) | catalogued as rs1186871744, COSV100485651; called by muse, mutect2, varscan2
- C2orf49 | c.9G>T p.G3= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as COSV99307616; called by muse, mutect2
- CARMIL3 | c.1455C>T p.S485= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV100549837; called by muse, mutect2
- CCDC40 | c.3081C>T p.S1027= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100163079; called by muse, mutect2, varscan2
- CD163 | c.2442G>A p.A814= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs759518221, COSV100776118; called by muse, varscan2
- CDHR2 | c.420C>T p.G140= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV99992159; called by muse, mutect2, varscan2
- CDX4 | c.357G>T p.V119= | Silent (SNP) | VAF 47/116 reads (41%) | catalogued as COSV100999154; called by muse, mutect2, varscan2
- CENPF | c.8376G>A p.Q2792= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as rs373154133; called by muse, mutect2, varscan2
- CEP128 | c.2772G>A p.E924= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs371653271, COSV99823578; called by muse, mutect2, varscan2
- CEP76 | c.1542G>A p.L514= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV100042962; called by muse, mutect2, varscan2
- CEP95 | c.789A>G p.L263= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as COSV101616339; called by muse, mutect2, varscan2
- CFAP100 | c.522G>A p.R174= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as rs1285788852, COSV100729417; called by muse, mutect2, varscan2
- CMYA5 | c.7911G>A p.P2637= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as rs370751761, COSV101483969; called by muse, mutect2, varscan2
- DENND2A | c.2970C>T p.S990= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs375723849; called by muse, mutect2, varscan2
- DRD2 | c.912G>A p.Q304= | Silent (SNP) | VAF 94/236 reads (40%) | catalogued as COSV100670061; called by muse, mutect2
- DYM | c.1824G>A p.K608= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as rs1206237584, COSV99494141; called by muse, mutect2, varscan2
- DZIP1 | c.2493C>T p.G831= (on ENST00000347108; = p.G812= on NM_014934.5) | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as rs554454725, COSV61267065; called by muse, mutect2, varscan2
- ECT2 | c.2022G>A p.Q674= (on ENST00000392692 / NM_001349098.2; = p.Q643= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99221869; called by muse, mutect2, varscan2
- EEF2 | c.2130C>T p.H710= | Silent (SNP) | VAF 31/176 reads (18%) | catalogued as rs776826199, COSV100500977; called by muse, mutect2, varscan2
- EPAS1 | c.690G>A p.Q230= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV99763628; called by muse, mutect2, varscan2
- EPB42 | c.144A>G p.P48= (on ENST00000441366 / NM_001114134.2; = p.P78= on NM_000119.3) | Silent (SNP) | VAF 8/107 reads (7%) | catalogued as rs1378910993, COSV100282139; called by muse, mutect2
- ESX1 | c.264G>A p.E88= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as rs200053829, COSV101006506; called by muse, mutect2, varscan2
- EXD3 | c.426C>T p.H142= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as rs371685558; called by muse, mutect2, varscan2
- FAM135B | c.2181C>T p.S727= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV52759036; called by muse, mutect2
- FAM135B | c.198C>T p.T66= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs1417595174, COSV50526462; called by muse, mutect2, varscan2
- FASN | c.6531C>T p.R2177= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs1160132362, COSV60754755; called by muse, mutect2, varscan2
- FERD3L | c.300C>T p.Y100= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs1410313015, COSV51762957; called by muse, varscan2
- FERMT1 | c.289C>T p.L97= | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as COSV54091904; called by muse, mutect2, varscan2
- FHL1 | c.6G>A p.A2= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV61779756; called by muse, mutect2, varscan2
- FLG2 | c.4851C>T p.H1617= | Silent (SNP) | VAF 134/311 reads (43%) | catalogued as rs199839343, COSV66166816; called by muse, mutect2, varscan2
- FOXA1 | c.1374G>A p.A458= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV99163793; called by muse, mutect2, varscan2
- FOXL2NB | c.258G>A p.A86= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV100374808; called by muse, mutect2, varscan2
- FREM2 | c.2007G>A p.Q669= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs1425945886, COSV99750676; called by muse, mutect2, varscan2
- FRMD1 | c.198G>A p.L66= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as COSV99350113; called by muse, mutect2
- FURIN | c.1071G>A p.R357= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs754571015, COSV99184782; called by muse, mutect2, varscan2
- GABRA2 | c.1077C>T p.S359= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs746609746, COSV62911580, COSV62921703; called by muse, mutect2, varscan2
- GABRQ | c.1030C>T p.L344= | Silent (SNP) | VAF 77/168 reads (46%) | catalogued as COSV100941428; called by muse, mutect2, varscan2
- GARS1 | c.1851C>T p.S617= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs377159922, COSV101220281; called by muse, varscan2
- GLG1 | c.540C>T p.C180= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as rs991393851, COSV99216247; called by muse, mutect2, varscan2
- GRM1 | c.255G>A p.T85= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as rs1562413730, COSV99264368; called by muse, mutect2, varscan2
- GRM1 | c.3537C>T p.Y1179= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99264339; called by muse, mutect2, varscan2
- GRM6 | c.528C>A p.S176= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as COSV99179918; called by muse, mutect2, varscan2
- H2BC4 | c.123C>T p.Y41= | Silent (SNP) | VAF 86/199 reads (43%) | catalogued as rs1214521441, COSV100019881, COSV100020016; called by muse, mutect2, varscan2
- HAUS5 | c.1458G>A p.A486= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs201817036, COSV52547428, COSV52549482; called by muse, mutect2, varscan2
- HEATR9 | c.597C>T p.Y199= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs377475394; called by muse, mutect2, varscan2
- HLA-DMA | c.363G>T p.P121= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs113629270, COSV100877685, COSV66386226; called by muse, mutect2, varscan2
- HNRNPH3 | c.183C>T p.F61= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV99769862; called by muse, mutect2
- HOXB7 | c.603G>A p.P201= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as rs760555343, COSV99494188; called by muse, mutect2, varscan2
- IGHV4-61 | c.52C>T p.L18= | Silent (SNP) | VAF 14/125 reads (11%) | called by muse, varscan2
- IGKV1-5 | c.117C>T p.D39= | Silent (SNP) | VAF 92/243 reads (38%) | catalogued as rs539985720; called by muse, mutect2, varscan2
- IL17RD | c.1239C>T p.H413= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs751029184, COSV99577074; called by muse, varscan2
- JMJD4 | c.1296C>T p.P432= | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as rs566082278, COSV59919204; called by muse, varscan2
- KCNA6 | c.87G>T p.P29= | Silent (SNP) | VAF 47/99 reads (47%) | catalogued as COSV99768963; called by muse, mutect2
- KCNE5 | c.168C>T p.G56= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV100927719; called by muse, mutect2, varscan2
- KIF18B | c.2526C>A p.L842= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV100192570; called by muse, mutect2, varscan2
- KIF3C | c.822C>T p.G274= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs774391507, COSV99267900; called by muse, mutect2, varscan2
- KLHL32 | c.822G>A p.Q274= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100987487; called by mutect2, varscan2
- KRTAP12-2 | c.168G>A p.L56= | Silent (SNP) | VAF 14/163 reads (9%) | catalogued as COSV100552029; called by muse, mutect2
- LARGE2 | c.1098C>T p.Y366= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs966726849, COSV57656947; called by muse, mutect2, varscan2
- LRIG3 | c.3099G>A p.S1033= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs539253869, COSV57862728; called by muse, varscan2
- MAPKAPK5 | c.801G>A p.E267= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV101534705; called by muse, mutect2, varscan2
- MED25 | c.300C>T p.G100= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs779662857, COSV100457959; called by muse, mutect2, varscan2
- MEGF6 | c.2436C>T p.R812= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV99621341; called by muse, mutect2, varscan2
- MET | c.1278C>T p.R426= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as rs748508881, COSV59265380; ClinVar: likely benign; called by muse, mutect2, varscan2
- MMP24 | c.1518G>A p.T506= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs773070007, COSV99864117; called by muse, varscan2
- MRC1 | c.288A>G p.E96= | Silent (SNP) | VAF 104/241 reads (43%) | catalogued as COSV100509695; called by muse, mutect2, varscan2
- MYO1H | c.240C>T p.S80= | Silent (SNP) | VAF 46/152 reads (30%) | catalogued as COSV100183976; called by muse, mutect2, varscan2
117 further variants in this file (0 protein-altering or splice-affecting, 88 silent, 29 other) are not listed here.
